CGCI case HTMCP-02-03-01016 — HIV+ Tumor Molecular Characterization Project - Lung Cancer (CGCI-HTMCP-LC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/25d787d5-0d12-4cba-b705-11c7debbecfe

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma with mixed subtypes: ICD-O-3 morphology code: 8255/3; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 54.6 years (19,939 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,165 days (5.9 years).
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (4 entries)
- Days to follow up: 0 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 941 days (2.6 years); Disease response: Tumor Free.
- Days to follow up: 2,165 days (5.9 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day -9,630.

Other clinical attributes
- Day -9,630: Risk factors: HIV/AIDS.
- Day -9,630: Comorbidities: HIV/AIDS.
- Day 0: Weight: 59 kg; Height: 152.4 cm; BMI: 25.4; CD4 count: 134; HIV viral load: 125.
- Day 0: AIDS risk factors: Pneumonia, NOS.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 14.

Biospecimens (3 samples)
- Sample HTMCP-02-03-01016-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-02-03-01016-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-02-03-01016-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma Mixed Subtype; Tumor status: Tumor free; Tobacco smoking age started: 26; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Performance status timing: Preoperative; Tobacco smoking history indicator: 2.
- Anatomic neoplasm subdivision list: Anatomic organ subdivision: Upper lobe.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 1985; Prior aids conditions: Pneumonia, recurrent.
- Primary pathology: Method initial path diagnosis: Tumor resection; Days from index date to tumor sample procurement: -5.
- Follow-up form: Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
